Somatic mutation profile of tumor specimen BA3389D (aliquot aq-BA3389D) from BEATAML1.0 case 2210, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 50.5 years (18,430 days).
Specimen BA3389D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48850fbf-022c-4ae6-8e8a-edcc4cc786c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2274D (Solid Tissue Normal), aliquot aq-BA2274D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/229e7ee9-7693-48de-bec8-e20eb0e02106

The open-access MAF lists 171 somatic variants for this specimen: 96 protein-altering or splice-affecting, 35 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 35, Intron 16, RNA 10, 5'UTR 5, 5'Flank 4, 3'UTR 4, In Frame Del 3, In Frame Ins 1, Splice Region 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GPRIN2 | c.298A>C p.T100P | Missense Mutation (SNP) | VAF 5/26 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs7090312; called by muse, mutect2, varscan2
- AMOT | c.2683_2703del p.A895_A901del (on ENST00000371959 / NM_001113490.1; = p.A486_A492del on NM_133265.3) | In Frame Del (DEL) | VAF 30/81 reads (37%) | catalogued as rs752098156; called by mutect2, varscan2
- ANKRD36 | c.1497C>A p.F499L | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.825); catalogued as rs976624205; called by muse, mutect2, varscan2
- APC2 | c.6247C>A p.R2083S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1462767309; called by muse, mutect2
- ARHGAP27 | c.553G>A p.G185S | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs748022267; called by muse, mutect2, varscan2
- ARHGEF19 | c.1487G>T p.R496L | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs147665966; called by muse, varscan2
- CALR3 | c.314G>A p.C105Y | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs747738664; called by muse, mutect2, varscan2
- CANX | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as rs750481212; called by muse, mutect2, varscan2
- CARS2 | c.1490T>C p.V497A | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs140567973; called by muse, mutect2, varscan2
- CCDC175 | c.2342C>A p.P781Q | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs138609862; called by muse, mutect2, varscan2
- CDC42EP5 | c.391C>A p.Q131K | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs150839818; called by muse, mutect2, varscan2
- CEP170B | c.487C>T p.R163C (on ENST00000453495; = p.R93C on NM_015005.3) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1009962128; called by muse, mutect2
- CHM | c.47C>T p.T16M | Missense Mutation (SNP) | VAF 65/130 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1021746178, COSV62564911; called by muse, mutect2, varscan2
- COL14A1 | c.2422G>A p.V808M | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs115676614; called by muse, mutect2, varscan2
- COL17A1 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 66/120 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs141512377; called by muse, mutect2, varscan2
- COL7A1 | c.4780C>T p.R1594W | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs267599859, COSV60394243; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CORIN | c.2008C>T p.R670C | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202243396; called by muse, mutect2, varscan2
- DLEC1 | c.1522G>A p.G508S | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs778982897; called by muse, mutect2, varscan2
- DRD4 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as rs373483649, COSV51562417; called by muse, mutect2, varscan2
- DSP | c.1816C>T p.R606W | Missense Mutation (SNP) | VAF 74/182 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs372467697; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EDEM1 | c.722_724dup p.I241dup | In Frame Ins (INS) | VAF 38/100 reads (38%) | catalogued as rs773958229; called by mutect2, varscan2
- EFEMP2 | c.422A>T p.H141L | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs148315164; ClinVar: uncertain significance; called by muse, varscan2
- EHMT1 | c.2767G>A p.E923K | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); catalogued as rs367643028; ClinVar: likely benign / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ERBB2 | c.734C>T p.T245M | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376183465; ClinVar: not provided; called by muse, mutect2, varscan2
- F11R | c.434T>C p.I145T | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.169); catalogued as rs138803658; called by muse, mutect2, varscan2
- FAM149B1 | c.1403G>A p.R468Q | Missense Mutation (SNP) | VAF 55/96 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774701845; called by muse, mutect2, varscan2
- FAM71E2 | c.1393G>A p.V465I | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs756582843; called by muse, varscan2
- FAN1 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs149291568; called by muse, mutect2, varscan2
- FTCD | c.1540A>G p.I514V | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs369754449; called by muse, mutect2, varscan2
- GHR | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 98/204 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs777751803, CM930314, COSV100050221, COSV50105999; called by muse, mutect2, varscan2
- GOLGA6L6 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 103/151 reads (68%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); catalogued as rs1333043415; called by muse, mutect2, varscan2
- HDAC6 | c.2272G>T p.G758C | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.392); catalogued as COSV61930112; called by muse, mutect2, varscan2
- HEYL | c.152T>C p.I51T | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1015499817; called by muse, mutect2, varscan2
- HSPA4L | c.2458T>A p.S820T | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs966571579; called by muse, mutect2, varscan2
- IARS1 | c.642A>T p.E214D | Missense Mutation (SNP) | VAF 59/125 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs267602314; called by muse, mutect2, varscan2
- IL1R2 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs199970902, COSV100207695; called by muse, mutect2, varscan2
- KATNIP | c.1046T>C p.V349A | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.496); catalogued as rs146475680; called by muse, varscan2
- KCNA5 | c.1540G>A p.V514I | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs1172712297, COSV52904278, COSV52905346, COSV52907390; called by muse, mutect2, varscan2
- KCNE2 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs148968498, CM097712; ClinVar: uncertain significance / not provided / likely benign; called by muse, mutect2, varscan2
- KCNK7 | c.463G>A p.V155I | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as rs375410314; called by muse, mutect2, varscan2
- KIF9 | c.1869G>C p.E623D (on ENST00000265529 / NM_001377474.1; = p.E558D on NM_022342.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.139); catalogued as rs373523302; called by muse, mutect2, varscan2
- KMT2D | c.12137G>A p.G4046E | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs750872313, COSV56414166; called by muse, mutect2, varscan2
- LAMA5 | c.2662G>T p.A888S | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.264); catalogued as rs775834837, COSV53353065, COSV53363953; called by muse, mutect2, varscan2
- LAMB2 | c.4070C>T p.P1357L | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.272); catalogued as rs141074838, COSV100026268; called by muse, mutect2, varscan2
- LETM2 | c.1241T>C p.V414A (on ENST00000379957 / NM_001286819.2; = p.V319A on NM_144652.3) | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1023918565; called by muse, mutect2, varscan2
- LSS | c.686T>A p.L229H | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs369733014; called by mutect2, varscan2
- MSLNL | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs201397841; called by muse, mutect2, varscan2
- MUC4 | c.9461C>T p.P3154L | Missense Mutation (SNP) | VAF 78/212 reads (37%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.722); catalogued as rs1553874692; called by muse, mutect2, varscan2
- MUC4 | c.6746C>T p.A2249V | Missense Mutation (SNP) | VAF 78/490 reads (16%) | SIFT tolerated, low confidence (0.92); PolyPhen possibly damaging (0.494); catalogued as rs71187735; called by muse, varscan2
- MYH10 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs747029840; called by muse, mutect2, varscan2
- MYH2 | c.1300G>A p.V434I | Missense Mutation (SNP) | VAF 109/262 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs143204063, COSV99063199; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEK1 | c.1923T>C p.H641= | Splice Region (SNP) | VAF 35/87 reads (40%) | catalogued as rs1045217433; called by muse, mutect2, varscan2
- NRROS | c.2011G>A p.V671I | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs200940623; called by muse, varscan2
- OIT3 | c.459G>C p.E153D | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1384017038; called by muse, mutect2, varscan2
- PHF7 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs754162505, COSV59979176; called by muse, mutect2, varscan2
- PIGT | c.925C>G p.L309V | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.251); catalogued as rs368878253; called by muse, mutect2, varscan2
- PLCB2 | c.452T>C p.I151T | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.379); catalogued as rs201004233; called by muse, mutect2, varscan2
- PLG | c.743C>T p.T248I | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as rs139012522; called by muse, mutect2, varscan2
- PNPLA7 | c.1669G>A p.A557T | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.767); catalogued as rs369129874; called by muse, mutect2, varscan2
- POTEA | c.1436A>G p.Y479C (on ENST00000519951 / NM_001005365.2; = p.Y433C on NM_001002920.1) | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs765333226; called by muse, mutect2, varscan2
- PRR14L | c.2765C>T p.S922F | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs770161725; called by muse, mutect2, varscan2
- RAD51AP1 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 78/154 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763582894, COSV57408917; called by muse, mutect2, varscan2
- RFX1 | c.1691C>T p.S564L | Missense Mutation (SNP) | VAF 33/45 reads (73%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as rs140854938; called by muse, mutect2, varscan2
- RGS19 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.693); catalogued as rs749194018, COSV100180918; called by mutect2, varscan2
- RNF38 | c.990_1016del p.H331_A339del | In Frame Del (DEL) | VAF 34/108 reads (31%) | catalogued as rs774713047; called by mutect2, varscan2
- RPS16 | c.250A>C p.I84L | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.279); catalogued as rs771944433; called by muse, mutect2, varscan2
- SDAD1 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1271587932; called by muse, mutect2, varscan2
- SEMA3F | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as rs371508526; called by muse, mutect2, varscan2
- SEMG2 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 78/139 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.685); catalogued as rs144655663; called by muse, mutect2, varscan2
- SLC39A14 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.401); catalogued as rs142534611; called by muse, mutect2, varscan2
- SNX32 | c.422_423del p.F141Sfs*50 | Frame Shift Del (DEL) | VAF 13/36 reads (36%) | catalogued as rs750080513; called by mutect2, pindel, varscan2
- SORBS3 | c.770A>G p.K257R | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as rs201180141; called by muse, mutect2, varscan2
- SUPT20HL1 | c.1534G>C p.A512P | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs199682391; called by muse, varscan2
- TACC1 | c.1432G>T p.A478S | Missense Mutation (SNP) | VAF 64/134 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.14); catalogued as rs113715454; called by muse, varscan2
- TAS1R3 | c.1964C>T p.A655V | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs150689635; called by muse, mutect2, varscan2
- TG | c.553G>C p.A185P | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1232081516; called by muse, varscan2
- TIAM2 | c.4652_4666del p.S1551_G1555del (on ENST00000529824; = p.S1522_G1526del on NM_012454.3) | In Frame Del (DEL) | VAF 5/51 reads (10%) | catalogued as rs747703724; called by muse*, pindel
- TNPO2 | c.1974G>C p.Q658H | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs770722987, COSV100790254; called by muse, mutect2, varscan2
- TRIM36 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as rs753593534; called by muse, mutect2, varscan2
- USP4 | c.1928C>T p.P643L | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (0.25); PolyPhen benign (0.158); catalogued as rs375163038; called by muse, mutect2, varscan2
- WDR6 | c.2026G>A p.D676N | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.351); catalogued as rs369792483; called by muse, mutect2, varscan2
- YLPM1 | c.1820C>G p.P607R | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.967); catalogued as rs779866964; called by muse, mutect2, varscan2
- ZNF155 | c.1115A>G p.Y372C | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766588468; called by muse, mutect2, varscan2
- ZNF831 | c.4900C>A p.Q1634K | Missense Mutation (SNP) | VAF 80/157 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs748931098; called by muse, mutect2, varscan2
- ACOT4 | c.564_569delinsTCAAAG p.A189_Y190delinsQS | Missense Mutation (ONP) | VAF 12/43 reads (28%) | called by pindel, varscan2*
- ALDH16A1 | c.305C>A p.A102D | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, varscan2
- ATP8A2 | c.151C>G p.L51V | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- EMC4 | c.66C>A p.S22R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by mutect2, varscan2
- EPB41L2 | c.1076G>C p.S359T | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- FGFR4 | c.1775G>T p.C592F | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- IMPG1 | c.500A>C p.K167T | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- LTB4R | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- MPP5 | c.668C>A p.A223D | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- NUP188 | c.4817C>G p.S1606C | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TUT7 | c.175G>A p.G59R | Missense Mutation (SNP) | VAF 99/172 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- VSIG10L | c.239G>A p.W80* | Nonsense Mutation (SNP) | VAF 33/72 reads (46%) | called by muse, mutect2, varscan2
- ADAM18 | c.1875T>C p.N625= | Silent (SNP) | VAF 44/97 reads (45%) | catalogued as rs906197131; called by muse, mutect2, varscan2
- ADGRA2 | c.3888G>A p.P1296= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs867984950; called by muse, mutect2, varscan2
- AGAP9 | c.1620C>T p.A540= | Silent (SNP) | VAF 88/557 reads (16%) | called by muse, mutect2, varscan2
- AKNAD1 | c.651A>G p.K217= | Silent (SNP) | VAF 44/68 reads (65%) | called by muse, mutect2, varscan2
- AR | c.1746C>T p.V582= | Silent (SNP) | VAF 81/153 reads (53%) | catalogued as rs145171897; ClinVar: likely benign; called by muse, mutect2, varscan2
- ASB12 | c.282C>A p.A94= | Silent (SNP) | VAF 61/144 reads (42%) | catalogued as rs141503461; called by muse, mutect2, varscan2
- BCL3 | c.327C>T p.P109= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs745656312; called by muse, varscan2
- BTBD8 | c.504A>G p.P168= | Silent (SNP) | VAF 40/104 reads (38%) | catalogued as rs1056173633; called by muse, mutect2, varscan2
- COL6A3 | c.9174G>T p.V3058= | Silent (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2, varscan2
- CYFIP1 | c.2808C>T p.V936= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as rs148724829; called by muse, mutect2, varscan2
- DNAH1 | c.10665G>A p.S3555= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as rs762880925, COSV70229623; called by muse, mutect2, varscan2
- GBA3 | c.1239A>C p.V413= | Silent (SNP) | VAF 40/76 reads (53%) | catalogued as rs574517248; called by muse, mutect2, varscan2
- GOLGA6L6 | c.1023G>A p.R341= | Silent (SNP) | VAF 36/284 reads (13%) | catalogued as rs1466385629; called by muse, mutect2, varscan2
- HEPH | c.2043C>A p.T681= (on ENST00000343002; = p.T414= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2
- KRT38 | c.390G>A p.A130= | Silent (SNP) | VAF 45/102 reads (44%) | catalogued as rs140403353; called by muse, mutect2, varscan2
- MAGEC1 | c.135C>T p.D45= | Silent (SNP) | VAF 30/77 reads (39%) | catalogued as rs781697121, COSV53568984; called by muse, mutect2, varscan2
- MED16 | c.603G>A p.T201= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs527765477, COSV54133112; called by muse, mutect2, varscan2
- MLLT10 | c.1125G>A p.L375= | Silent (SNP) | VAF 25/49 reads (51%) | called by muse, mutect2, varscan2
- MROH1 | c.1329C>G p.P443= | Silent (SNP) | VAF 8/10 reads (80%) | called by muse, varscan2
- MST1R | c.1053G>A p.V351= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs371551244; called by muse, mutect2, varscan2
- MUC4 | c.6513A>G p.T2171= | Silent (SNP) | VAF 67/541 reads (12%) | catalogued as rs763175522; called by muse, varscan2
- NEURL3 | c.219C>T p.C73= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as rs1338678423; called by muse, varscan2
- NUP214 | c.6060C>T p.S2020= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs147668436; called by muse, varscan2
- OR14K1 | c.837A>G p.A279= | Silent (SNP) | VAF 68/140 reads (49%) | catalogued as COSV99315407; called by muse, mutect2, varscan2
- PCNX3 | c.4890C>T p.A1630= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as rs370639193; called by muse, mutect2, varscan2
- PLS3 | c.1518C>A p.T506= | Silent (SNP) | VAF 34/62 reads (55%) | catalogued as rs35525703, COSV99171643; called by muse, mutect2, varscan2
- PSG6 | c.303T>C p.Y101= | Silent (SNP) | VAF 34/83 reads (41%) | called by muse, mutect2, varscan2
- RPL4 | c.417T>G p.S139= | Silent (SNP) | VAF 20/34 reads (59%) | called by muse, mutect2, varscan2
- SLC22A3 | c.1296A>G p.A432= | Silent (SNP) | VAF 114/223 reads (51%) | catalogued as rs368718347; called by muse, mutect2, varscan2
- SLIT2 | c.3219C>T p.C1073= | Silent (SNP) | VAF 38/77 reads (49%) | catalogued as rs372434910; called by muse, mutect2, varscan2
- TBC1D8 | c.1848G>A p.V616= | Silent (SNP) | VAF 38/74 reads (51%) | catalogued as rs369454442; called by muse, mutect2, varscan2
- TMEM145 | c.9C>T p.P3= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs1179083155; called by muse, mutect2, varscan2
- TTLL5 | c.2052C>T p.L684= | Silent (SNP) | VAF 46/127 reads (36%) | catalogued as rs374872936; called by muse, mutect2, varscan2
- WDR64 | c.1029T>C p.D343= | Silent (SNP) | VAF 18/41 reads (44%) | called by muse, mutect2, varscan2
- XRCC3 | c.309T>C p.T103= | Silent (SNP) | VAF 26/66 reads (39%) | called by muse, mutect2, varscan2
- AC008619.1 | chr5:170483113 G>C | 3'Flank (SNP) | VAF 14/27 reads (52%) | catalogued as rs562764819; called by muse, varscan2
- AC112198.2 | n.129G>C | RNA (SNP) | VAF 33/66 reads (50%) | catalogued as rs756821743; called by muse, mutect2, varscan2
- ADAM3A | n.2371dup | RNA (INS) | VAF 82/205 reads (40%) | catalogued as rs111243148; called by mutect2, pindel, varscan2
- AGAP12P | n.1621C>T | RNA (SNP) | VAF 68/142 reads (48%) | called by muse, varscan2
- AK2 | c.372+14G>A | Intron (SNP) | VAF 89/201 reads (44%) | catalogued as rs368660217; called by muse, mutect2, varscan2
- AP003062.1 | n.648G>A | RNA (SNP) | VAF 102/584 reads (17%) | catalogued as rs868215814; called by muse, varscan2
- ATCAY | c.1106+1411C>T | Intron (SNP) | VAF 17/39 reads (44%) | catalogued as rs1308595348; called by muse, mutect2, varscan2
- BCAP31 | c.-45+319_-45+320delinsTTAC | Intron (INS) | VAF 25/47 reads (53%) | catalogued as rs386828566; called by pindel, varscan2*
- C19orf71 | chr19:3538737 C>T | 5'Flank (SNP) | VAF 49/86 reads (57%) | catalogued as rs956084786; called by muse, mutect2, varscan2
- CBWD3 | c.430+2337C>G | Intron (SNP) | VAF 8/12 reads (67%) | catalogued as rs868938332; called by mutect2, varscan2
- CHRNA7 | c.-29G>A | 5'UTR (SNP) | VAF 6/10 reads (60%) | catalogued as rs939229019; called by muse, varscan2
- CTPS2 | c.1393+236G>A | Intron (SNP) | VAF 26/51 reads (51%) | catalogued as rs776984158; called by muse, varscan2
- DCUN1D4 | c.616-15T>C | Intron (SNP) | VAF 36/92 reads (39%) | catalogued as rs1292044777; called by muse, mutect2, varscan2
- DECR1 | c.-16G>C | 5'UTR (SNP) | VAF 26/68 reads (38%) | catalogued as rs201183578; called by muse, mutect2, varscan2
- GTF2IP1 | n.1414C>T | RNA (SNP) | VAF 38/40 reads (95%) | called by mutect2, varscan2
- HACD1 | c.376-37A>C | Intron (SNP) | VAF 52/103 reads (50%) | catalogued as rs377244390; called by muse, mutect2, varscan2
- HERC2P2 | n.759G>C | RNA (SNP) | VAF 36/178 reads (20%) | catalogued as rs755779731; called by muse, mutect2, varscan2
- HERC2P3 | n.2274A>G | RNA (SNP) | VAF 51/321 reads (16%) | catalogued as rs376368073; called by muse, varscan2
- HERC2P3 | n.610A>G | RNA (SNP) | VAF 80/600 reads (13%) | catalogued as rs575743574; called by muse, varscan2
- IKBKB | c.388+9C>T | Intron (SNP) | VAF 37/96 reads (39%) | catalogued as rs140937081; ClinVar: likely benign; called by muse, mutect2, varscan2
- MST1 | c.1016+10G>C | Intron (SNP) | VAF 45/93 reads (48%) | catalogued as rs766191558; called by muse, varscan2
- NPIPA5 | chr16:15380937 G>A | 5'Flank (SNP) | VAF 23/156 reads (15%) | catalogued as rs1265572627; called by muse, mutect2, varscan2
- PMPCA | c.633+29G>A | Intron (SNP) | VAF 69/147 reads (47%) | catalogued as rs369879456; called by muse, mutect2, varscan2
- PPIL2 | c.-2C>G | 5'UTR (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2, varscan2
- RAB3IP | c.1279-11A>G | Intron (SNP) | VAF 71/190 reads (37%) | catalogued as rs1173534918; called by muse, mutect2, varscan2
- RBCK1 | c.168-210C>T | Intron (SNP) | VAF 32/77 reads (42%) | catalogued as rs371483995; called by muse, mutect2, varscan2
- RN7SL106P | chr15:23163987 G>A | 5'Flank (SNP) | VAF 34/256 reads (13%) | catalogued as rs781652721; called by muse, varscan2
- RNFT1 | c.693-221T>G | Intron (SNP) | VAF 64/129 reads (50%) | catalogued as rs536498904; called by muse, mutect2, varscan2
- RNU1-6P | chr1:16536102 G>A | 5'Flank (SNP) | VAF 37/314 reads (12%) | catalogued as rs761795600; called by muse, mutect2, varscan2
- SCD5 | c.569+19680G>A | Intron (SNP) | VAF 97/208 reads (47%) | catalogued as rs1307315261; called by muse, mutect2, varscan2
- TAAR3P | n.636A>G | RNA (SNP) | VAF 50/115 reads (43%) | catalogued as rs866852212; called by muse, varscan2
- TRPM8 | c.*80G>A | 3'UTR (SNP) | VAF 50/118 reads (42%) | catalogued as rs201477771, COSV100223539; called by mutect2, varscan2
- UQCRB | c.*441T>C | 3'UTR (SNP) | VAF 68/128 reads (53%) | catalogued as rs535073837; called by muse, varscan2
- USP4 | c.696-5489_696-5473del | Intron (DEL) | VAF 20/58 reads (34%) | catalogued as rs751102726; called by mutect2, pindel, varscan2
- WASH8P | n.987C>T | RNA (SNP) | VAF 35/218 reads (16%) | catalogued as rs782658559; called by muse, mutect2, varscan2
- WASHC2C | c.-20C>T | 5'UTR (SNP) | VAF 14/30 reads (47%) | catalogued as rs777715600; called by muse, mutect2, varscan2
- ZMAT4 | c.103-19000A>C | Intron (SNP) | VAF 44/102 reads (43%) | catalogued as rs943314668; called by muse, mutect2, varscan2
- ZNF7 | c.-40T>C | 5'UTR (SNP) | VAF 21/51 reads (41%) | catalogued as rs1483633115; called by muse, mutect2, varscan2
- ZNF747 | c.*285_*287del | 3'UTR (DEL) | VAF 9/12 reads (75%) | catalogued as rs1233438041; called by mutect2, varscan2
- ZNF778 | c.*4541G>A | 3'UTR (SNP) | VAF 61/71 reads (86%) | catalogued as rs187745392; called by muse, mutect2, varscan2
